Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A3HE, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A3HE-01A (Primary Tumor).

[page 1 of 2]
Patient Name: [REDACTED]

DOB: [REDACTED]

Accession: [REDACTED]

MRN: [REDACTED]

PAN: [REDACTED]

Surgical Pathology Report

Final

1 CD-0-3

carcinoma, squamous cell, NOS
8070/3

Site: cervix, NOS c53.9

hw 12/5/11

SURGICAL PATHOLOGY REPORT FINAL

Patient Name: [REDACTED]

Address: [REDACTED]

Gender: F

DOB: [REDACTED] Age: [REDACTED]

Service: Gynecology

Location: [REDACTED]

MRN: [REDACTED]

Hospital #: [REDACTED]

Patient Type: [REDACTED]

Accession #: [REDACTED]

Taken: [REDACTED]

Received: [REDACTED]

Accessioned: [REDACTED]

Reported: [REDACTED]

Physician(s): [REDACTED]

M.D.

Other Related Clinical Data:

DIAGNOSIS:

UTERUS, CERVIX, MASS, BIOPSY

- POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA

[REDACTED] By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

M.D.

***Report Electronically Reviewed and Signed Out By [REDACTED]

M.D.***

Microscopic Description and Comment:

Microscopic examination substantiates the above cited diagnosis. [REDACTED] has reviewed this case and concurs.

M.D.

History:

The patient is a [REDACTED] year old woman who presents with a cervical mass. Operative procedure: Cervical mass biopsy.

Specimen(s) Received:

A: CERVICAL MASS

Gross Description

The specimen is received in a formalin-filled container labeled "[REDACTED]" and "cervical biopsy." It consists of two irregular gray-white tissue fragments measuring 1.2 x 0.5 x 0.4 cm and 0.9 x 0.3 x 0.3 cm. The larger fragment is bisected. Labeled A1. Jar 0.

M.S.

The performance characteristics of some immunohistochemical stains, fluorescence in-situ hybridization tests and immunophenotyping by flow cytometry cited in

Reviewer Initials: [REDACTED]		

[page 2 of 2]
Patient Name: [REDACTED]

DOB: [REDACTED]

Accession: [REDACTED]

MRN: [REDACTED]

PAN: [REDACTED]

this report (if any) were determined by the Surgical Pathology Department at [REDACTED] as part of an ongoing quality assurance program and in compliance with federally mandated regulations drawn from the Clinical Laboratory Improvement Act of 1988 (CLIA '88). Some of these tests rely on the use of "analyte specific reagents" and are subject to specific labeling requirements by the US Food and Drug Administration. Such diagnostic tests may only be performed in a facility that is certified by the Department of Health and Human Services as a high complexity laboratory under CLIA '88. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. Nevertheless, federal rules concerning the medical use of analyte specific reagents require that the following disclaimer be attached to the report:

This test was developed and its performance characteristics determined by the Surgical Pathology Department of [REDACTED]. It has not been cleared or approved by the U. S. Food and Drug Administration.

Source: NCI Genomic Data Commons file 97ae2491-b1b4-4e6d-935b-f03a405078a8 (TCGA-C5-A3HE.8D7665DB-F820-4545-81C8-233A3AE3F9C9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).